Somatic mutation profile of tumor specimen MMRF_1281_1_BM_CD138pos (aliquot MMRF_1281_1_BM_CD138pos_T2_TSE61_K03764) from MMRF case MMRF_1281, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 37.3 years (13,638 days).
Specimen MMRF_1281_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99ac31ac-c226-4e81-8996-35827898e77d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1281_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1281_1_PB_Whole_C1_TSE61_K03765; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3284cba6-4e75-438c-85f1-f35df031d608

The open-access MAF lists 76 somatic variants for this specimen: 35 protein-altering or splice-affecting, 4 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 28, Silent 4, 5'UTR 4, 5'Flank 3, Nonsense Mutation 2, RNA 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- B4GALNT3 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs200514267; called by muse, mutect2
- CAMK1 | c.888_890del p.K296del | In Frame Del (DEL) | VAF 64/138 reads (46%) | catalogued as rs745642487; called by pindel, varscan2
- DMPK | c.1700G>A p.G567D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.33); catalogued as rs773600679, COSV52180453; called by muse, mutect2, varscan2
- DUSP2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as rs1408044070; called by muse, mutect2
- FLG | c.12069T>A p.D4023E | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV64248556; called by muse, mutect2, varscan2
- FOXN4 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV54493828; called by muse, mutect2, varscan2
- FRMD7 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs1295026486; called by muse, mutect2, varscan2
- JADE1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 125/240 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753231987, COSV56906955; called by muse, mutect2, varscan2
- NANOS2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs750395701, COSV58025375; called by muse, mutect2
- PLEKHA4 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769937370, COSV104372475; called by muse, mutect2
- PRUNE2 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65048986; called by muse, mutect2
- SPEG | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs376823807; called by muse, mutect2
- BEND4 | c.1198T>C p.W400R | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRINP3 | c.1580C>A p.P527H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- C1QL2 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CIITA | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 63/125 reads (50%) | called by muse, mutect2, varscan2
- CSPP1 | c.3328G>A p.G1110R (on ENST00000676605; = p.G1069R on NM_024790.6) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- DDX41 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 31/441 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2
- DGKD | c.1067A>G p.N356S (on ENST00000264057 / NM_152879.3; = p.N312S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.539); called by muse, mutect2
- DHX29 | c.219T>A p.N73K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2
- DSC1 | c.1569C>A p.H523Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FOXA1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2
- GRN | c.1103A>T p.N368I | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2
- HLA-DPA1 | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- NPHP4 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR4A16 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); called by muse, mutect2
- PEG10 | c.445G>T p.A149S (on ENST00000482108 / NM_001040152.2; = p.A183S on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/434 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); called by muse, mutect2
- RABL6 | c.1076C>A p.S359Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TXNL4A | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 108/201 reads (54%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ZC3H13 | c.2891A>T p.K964M | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF319 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF718 | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ZNF780A | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.014); called by muse, mutect2
- GLI2 | c.2367C>T p.R789= (on ENST00000361492 / NM_001374353.1; = p.R806= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/32 reads (66%) | called by muse, mutect2, varscan2
- OR8D4 | c.228C>T p.V76= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV100361724; called by muse, mutect2, varscan2
- VWA5B2 | c.3648C>T p.A1216= | Silent (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- WWP1 | c.699C>G p.L233= | Silent (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- ADGRL4 | c.*293A>G | 3'UTR (SNP) | VAF 4/7 reads (57%) | called by muse, mutect2
- ALG3 | chr3:184249311 C>A | 5'Flank (SNP) | VAF 48/82 reads (59%) | catalogued as rs1401833250, COSV61080880; called by muse, mutect2, varscan2
- ANKRD29 | c.*251A>G | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- APPL1 | c.*2998C>T | 3'UTR (SNP) | VAF 14/21 reads (67%) | catalogued as rs566930082; called by muse, varscan2
- ARIH1 | c.*1311dup | 3'UTR (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- BDNF | c.*408A>T | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- CADM1 | c.*2199A>C | 3'UTR (SNP) | VAF 35/78 reads (45%) | catalogued as rs550202781, COSV59007181; called by muse, mutect2, varscan2
- CHST3 | c.*826A>G | 3'UTR (SNP) | VAF 83/195 reads (43%) | called by muse, mutect2, varscan2
- DCUN1D5 | c.*9720C>T | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- GIT1 | c.*417C>T | 3'UTR (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- GPSM1 | chr9:136324178 G>T | 5'Flank (SNP) | VAF 133/405 reads (33%) | called by muse, mutect2, varscan2
- IHO1 | c.*296C>T | 3'UTR (SNP) | VAF 11/117 reads (9%) | catalogued as rs1022168862; called by muse, mutect2
- IL20RB | c.*292G>T | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- KCNA1 | c.-108C>T | 5'UTR (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- KCNMB1 | chr5:170389453 C>A | 5'Flank (SNP) | VAF 83/215 reads (39%) | called by muse, mutect2, varscan2
- KRT25 | c.*211T>C | 3'UTR (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- LINC01144 | n.69G>A | RNA (SNP) | VAF 56/102 reads (55%) | catalogued as rs1327930283; called by muse, mutect2, varscan2
- LURAP1L | c.-309G>A | 5'UTR (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- MAP3K1 | c.*2277A>T | 3'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, varscan2
- MARCHF1 | c.*1791dup | 3'UTR (INS) | VAF 20/58 reads (34%) | called by pindel, varscan2
- MPZL2 | c.-5C>T | 5'UTR (SNP) | VAF 68/169 reads (40%) | catalogued as COSV54048821; called by muse, mutect2, varscan2
- MTHFD1L | c.*183G>C | 3'UTR (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- MYO5A | c.*3202G>A | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- PRRC2C | c.*926C>G | 3'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- PTAR1 | c.*1372G>T | 3'UTR (SNP) | VAF 3/40 reads (8%) | catalogued as rs980370203; called by muse, mutect2
- PUS10 | c.*192G>C | 3'UTR (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- RBM15B | c.*3791T>C | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- RNF112 | c.*782C>A | 3'UTR (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- RPE | c.*36C>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- STIMATE-MUSTN1 | chr3:52833134 G>A | 3'Flank (SNP) | VAF 16/42 reads (38%) | catalogued as rs1444026525; called by muse, varscan2
- TMOD3 | c.*259T>C | 3'UTR (SNP) | VAF 38/58 reads (66%) | catalogued as COSV57944256; called by muse, mutect2, varscan2
- TOP1 | c.-233A>G | 5'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs975819527; called by muse, mutect2
- UPF1 | c.*808G>A | 3'UTR (SNP) | VAF 12/200 reads (6%) | catalogued as rs1008345921; called by muse, mutect2
- WSCD1 | c.*400G>A | 3'UTR (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- ZEB2 | c.*604C>A | 3'UTR (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- ZNF578 | c.*103A>C | 3'UTR (SNP) | VAF 21/461 reads (5%) | called by muse, mutect2
- ZNF691 | c.*543A>G | 3'UTR (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
